Somatic mutation profile of tumor specimen TCGA-FR-A7UA-06A (aliquot TCGA-FR-A7UA-06A-32D-A34U-08) from TCGA case TCGA-FR-A7UA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.9 years (24,792 days).
Specimen TCGA-FR-A7UA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee5f571b-fd85-4e58-84a6-b870d5a458f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A7UA-10A (Blood Derived Normal), aliquot TCGA-FR-A7UA-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/302dc4ee-86ce-4bb3-a45f-f7ea9d6dcb8c

The open-access MAF lists 183 somatic variants for this specimen: 127 protein-altering or splice-affecting, 50 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 50, Nonsense Mutation 10, Splice Site 3, Intron 3, RNA 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1446260379, COSV100578330; called by muse, mutect2, varscan2
- ACAN | c.4528C>T p.P1510S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV100716857; called by mutect2, varscan2
- ADAMTSL1 | c.435T>A p.Y145* | Nonsense Mutation (SNP) | VAF 24/193 reads (12%) | catalogued as COSV99440593; called by muse, mutect2, varscan2
- ADCY2 | c.2819C>T p.T940I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1307291247, COSV100601520; called by muse, mutect2, varscan2
- ADGRL2 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1195606200, COSV99586828; called by muse, mutect2
- AIFM1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 39/399 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99780696; called by muse, mutect2, varscan2
- AKAP4 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62074237; called by muse, mutect2, varscan2
- ANXA13 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1288237211, COSV99146029; called by muse, mutect2
- ASZ1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99497696; called by muse, mutect2, varscan2
- BTBD11 | c.1386G>A p.W462* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99774554; called by muse, mutect2
- C1orf94 | c.1444C>T p.Q482* (on ENST00000488417 / NM_001134734.2; = p.Q292* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV64912975; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- CACNA1F | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV100544288; called by muse, mutect2
- CCDC122 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs747854273, COSV99865785; called by muse, mutect2, varscan2
- CCDC68 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100491572; called by muse, mutect2
- CDH8 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV100179215; called by muse, mutect2, varscan2
- CENPE | c.4271T>C p.L1424P | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV99476796; called by muse, mutect2
- CEP135 | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV57259042, COSV57260380; called by muse, mutect2, varscan2
- CILK1 | c.1694C>T p.S565F (on ENST00000350082 / NM_001375397.1; = p.S558F on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100607442; called by muse, mutect2, varscan2
- CILP2 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772620044, COSV99364235; called by muse, mutect2
- CPA1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99163207; called by muse, mutect2
- CSMD3 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1444297700, COSV52103573; called by muse, mutect2, varscan2
- DAAM2 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV99224294; called by muse, mutect2
- DDX53 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs778044990, COSV100028644; called by muse, mutect2, varscan2
- DEFB116 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs553935240, COSV68722428; called by muse, mutect2, varscan2
- DHRS3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66108456; called by muse, mutect2
- DPPA4 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509998; called by muse, varscan2
- EPPK1 | c.6527G>A p.G2176E | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554659141, COSV101599718; called by muse, mutect2
- ERICH3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200091670, COSV100443195, COSV58604205; called by muse, mutect2, varscan2
- ETV5 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as rs759682748, COSV60500796; called by muse, mutect2, varscan2
- FAM47B | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1300814206, COSV61454021; called by muse, mutect2
- FANCB | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.229); catalogued as COSV60760203; called by muse, mutect2
- FLG | c.3769T>C p.S1257P | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100910383; called by muse, mutect2
- FRMPD2 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs782475729, COSV59717322; called by muse, mutect2, varscan2
- FRYL | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99975438, COSV99976813; called by muse, mutect2, varscan2
- FUT9 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.326); catalogued as rs866474183, COSV56142137; called by muse, mutect2, varscan2
- GABRA2 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs867537932, COSV100733706; called by muse, mutect2
- GABRE | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.411); catalogued as COSV100944197; called by muse, mutect2, varscan2
- GATM | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376982466; ClinVar: not provided; called by muse, mutect2, varscan2
- GDF3 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs755337048, COSV61712020; called by muse, mutect2, varscan2
- GJC1 | c.557T>G p.V186G | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100395110; called by muse, mutect2, varscan2
- HNF4A | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.104); catalogued as rs769972803, COSV100290981; called by muse, mutect2, varscan2
- IGF2BP1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.206); catalogued as COSV99288172; called by muse, mutect2, varscan2
- IKZF1 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as COSV100497861; called by muse, mutect2, varscan2
- KCNH4 | c.2798G>A p.R933K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV99236671; called by muse, mutect2, varscan2
- KCNS1 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100066990; called by muse, mutect2, varscan2
- KLC3 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101228780; called by muse, mutect2
- LINGO2 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV58059820; called by muse, mutect2, varscan2
- LRP1B | c.10906C>T p.Q3636* | Nonsense Mutation (SNP) | VAF 21/130 reads (16%) | catalogued as COSV101250966; called by muse, mutect2, varscan2
- LRRTM3 | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100791435; called by muse, mutect2, varscan2
- MAGEA10 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs748262488, COSV99726548; called by muse, mutect2
- MAGEA4 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV52343101; called by muse, mutect2, varscan2
- MGAM | c.4573G>A p.G1525R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527353; called by muse, mutect2
- MORC1 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1173188517, COSV51719800, COSV51732735; called by muse, mutect2
- MTR | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM021639, COSV100855203; called by muse, mutect2
- MYH2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.304); catalogued as COSV55436452; called by muse, mutect2
- NETO1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100198096; called by muse, mutect2
- NLGN2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100259177; called by muse, mutect2, varscan2
- NLRP4 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as rs868526766, COSV56723076; called by muse, mutect2, varscan2
- NOMO1 | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1357773385, COSV55057659, COSV99814442; called by muse, mutect2
- NPY | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386633782, COSV99635619; called by muse, mutect2, varscan2
- OR13C2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101604853; called by muse, mutect2, varscan2
- OR2M7 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 25/424 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.033); catalogued as COSV58741283; called by muse, mutect2
- OR4Q3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 11/295 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV59177523; called by muse, mutect2
- OR5H1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100641607; called by muse, mutect2, varscan2
- OR7D2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs372189901; called by muse, mutect2, varscan2
- OR8D4 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV58431652; called by muse, mutect2
- OTOGL | c.5383C>T p.Q1795* (on ENST00000547103; = p.Q1786* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100086522; called by muse, mutect2, varscan2
- OTOP2 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 27/363 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100508753; called by muse, mutect2
- P2RX4 | c.388G>C p.A130P | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV100078662; called by muse, mutect2
- PCDHGA9 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); catalogued as rs772617526, COSV99529091; called by mutect2, varscan2
- PCDHGB3 | c.2071C>T p.H691Y | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866767017, COSV53918337; called by muse, mutect2, varscan2
- PCLO | c.10604G>A p.R3535K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.12); catalogued as rs867781120, COSV100426641; called by muse, mutect2
- PCLO | c.8828T>G p.V2943G | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100426646; called by muse, mutect2, varscan2
- PCYT1B | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100770417; called by muse, mutect2, varscan2
- PDE1C | c.1583-1G>A p.X528_splice | Splice Site (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100370612; called by muse, mutect2, varscan2
- PDE6B | c.2353-1G>A p.X785_splice | Splice Site (SNP) | VAF 19/153 reads (12%) | catalogued as COSV99726836; called by muse, mutect2, varscan2
- PLCZ1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.631); catalogued as COSV56859537, COSV99856951; called by muse, mutect2, varscan2
- PNMA5 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868912160, COSV100721563; called by muse, mutect2, varscan2
- POGZ | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99652221; called by muse, mutect2, varscan2
- PRKX | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV99467503; called by muse, mutect2
- PSD4 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV99830764; called by muse, mutect2, varscan2
- PSG6 | c.818G>A p.W273* | Nonsense Mutation (SNP) | VAF 32/378 reads (8%) | catalogued as COSV99413448; called by muse, mutect2
- PSG8 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 27/468 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs781513768, COSV60610706; called by muse, mutect2
- PSTPIP2 | c.609A>T p.E203D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV101297331; called by muse, mutect2
- PYGO1 | c.992G>C p.R331P | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as COSV100114421; called by muse, mutect2
- RAI1 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs778539478, COSV99883147; called by muse, mutect2
- SCN1A | c.3394T>A p.F1132I (on ENST00000303395 / NM_001202435.3; = p.F1121I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV100318985; called by muse, mutect2, varscan2
- SCNN1G | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55597297, COSV55599779; called by mutect2, varscan2
- SEC16B | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100381156; called by muse, mutect2, varscan2
- SEMA3E | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100316984; called by muse, mutect2, varscan2
- SIGLECL1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.775); catalogued as COSV100323802; called by muse, mutect2, varscan2
- SLC30A1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100879087; called by muse, mutect2
- SLC44A5 | c.1468A>T p.M490L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100900861; called by muse, mutect2, varscan2
- SLC9C2 | c.1488G>A p.M496I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62943263; called by muse, mutect2
- SMCR8 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1567758020, COSV100328870; called by muse, mutect2, varscan2
- SORCS3 | c.2918G>A p.G973E | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866209538, COSV63795853, COSV63797443; called by muse, mutect2, varscan2
- SPAG6 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100509879; called by muse, mutect2, varscan2
- SRRM2 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV100070026; called by muse, mutect2
- SYNE1 | c.21461C>A p.S7154Y (on ENST00000367255 / NM_182961.4; = p.S7083Y on NM_033071.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55016429, COSV99550991; called by muse, mutect2
- TMEM165 | c.498A>C p.L166F | Missense Mutation (SNP) | VAF 5/120 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101189646; called by muse, mutect2
- TMEM200A | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758556; called by muse, mutect2, varscan2
- TMPRSS11E | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV59521575; called by muse, mutect2, varscan2
- TRANK1 | c.5879C>T p.S1960F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100081189; called by muse, mutect2, varscan2
- TRIM10 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100938773; called by muse, mutect2
- TRIML1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100205643; called by muse, mutect2
- TTLL10 | c.1391C>T p.T464I (on ENST00000379289 / NM_001130045.2; = p.T391I on NM_153254.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV101016350; called by muse, mutect2
- TTLL13P | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.177); catalogued as COSV100296361, COSV60036444; called by muse, mutect2
- TTN | c.91824G>A p.W30608* (on ENST00000591111; = p.W23184* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 10/174 reads (6%) | catalogued as COSV60175772; called by muse, mutect2
- UGT2A2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.231); catalogued as COSV54138004; called by muse, mutect2, varscan2
- WNK3 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV100670653; called by muse, mutect2, varscan2
- WNT2 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV55410467, COSV99625639; called by muse, mutect2, varscan2
- ZBTB33 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV58532966; called by muse, mutect2
- ZNF557 | c.977C>T p.S326L (on ENST00000414706 / NM_001044388.2; = p.S333L on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs1366522171, COSV53273725; called by muse, mutect2, varscan2
- ZNF595 | c.1211C>A p.A404D | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100227379; called by muse, mutect2
- ZNF611 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100159937; called by muse, mutect2
- ZNF682 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV100653182; called by muse, mutect2
- ZNF713 | c.889G>A p.G297R (on ENST00000633730 / NM_001366796.2; = p.G310R on NM_182633.3) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448702; called by muse, mutect2, varscan2
- ZSCAN31 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100716842; called by muse, mutect2
- C17orf98 | c.190T>A p.L64M | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAPTM5 | c.511-1G>A p.X171_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- RCAN3 | c.460_462delinsTTA p.P154L | Missense Mutation (TNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by mutect2*, pindel, varscan2*
- SEMA3C | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2
- SSU72P8 | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2
- TRBV4-2 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- ANOS1 | c.954C>T p.P318= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs763444046, COSV52916274, COSV52916937; called by muse, mutect2, varscan2
- CASR | c.1956C>T p.F652= (on ENST00000490131; = p.F729= on NM_000388.4) | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99948384; called by muse, mutect2
- CCDC60 | c.1431G>A p.V477= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV59543297; called by muse, mutect2
- CCT8L2 | c.1656C>T p.I552= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100742530; called by muse, mutect2
- CPXM2 | c.927C>T p.T309= | Silent (SNP) | VAF 8/149 reads (5%) | catalogued as rs1038054120, COSV99580790; called by muse, mutect2
- CSF2RB | c.129C>T p.I43= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99453170; called by muse, mutect2
- CSMD2 | c.6507G>A p.R2169= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53899363; called by muse, mutect2, varscan2
- CUX2 | c.268C>T p.L90= | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as COSV99918421, COSV99919037; called by muse, mutect2
- DCST1 | c.1281G>A p.R427= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV55056568; called by muse, mutect2, varscan2
- DMXL2 | c.6150C>T p.I2050= | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as COSV99195916; called by muse, mutect2
- DNAH2 | c.2118G>A p.K706= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV101208948; called by muse, mutect2
- FAT3 | c.6475C>T p.L2159= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99960911; called by muse, mutect2, varscan2
- FKBP5 | c.1068G>A p.R356= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV61881798; called by muse, mutect2, varscan2
- GBE1 | c.2073G>A p.V691= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV101450066; called by muse, mutect2, varscan2
- HACL1 | c.1179C>T p.F393= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs752404751, COSV58255221; called by muse, mutect2
- HEPH | c.2715G>A p.K905= (on ENST00000343002; = p.K638= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV100293957, COSV57974140; called by muse, mutect2
- IL22RA1 | c.1122C>T p.F374= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99582711; called by muse, mutect2
- JCAD | c.1998C>T p.F666= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV64760168; called by muse, mutect2, varscan2
- LMTK3 | c.2967G>A p.L989= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1022607132, COSV99539824; called by muse, mutect2
- MAGED2 | c.699G>A p.R233= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV54499213; called by muse, mutect2
- MYCN | c.1164C>T p.I388= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV99807984; called by muse, mutect2, varscan2
- NBEA | c.4878C>T p.F1626= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs998674929, COSV59758795, COSV59763306; called by muse, mutect2
- NEBL | c.1266G>A p.G422= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1290461637, COSV65803318, COSV65804444; called by muse, mutect2, varscan2
- NGLY1 | c.1521T>G p.V507= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV99769993; called by muse, mutect2
- OIT3 | c.831C>T p.I277= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV100467595; called by muse, mutect2, varscan2
- OR10H4 | c.849C>T p.F283= | Silent (SNP) | VAF 28/213 reads (13%) | catalogued as COSV100437654; called by muse, mutect2, varscan2
- OR10H5 | c.51C>T p.F17= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV100454617; called by muse, mutect2
- OR56B1 | c.951C>T p.A317= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV57723969; called by muse, mutect2
- PAGE5 | c.216G>A p.G72= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99215671; called by muse, mutect2
- PCDHA13 | c.1365C>T p.F455= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV56493219; called by muse, mutect2, varscan2
- PCDHGA9 | c.663T>G p.R221= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99529095; called by muse, mutect2, varscan2
- PCSK5 | c.1461C>T p.S487= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as COSV100949377; called by muse, mutect2, varscan2
- PDE1C | c.1785G>A p.E595= | Silent (SNP) | VAF 44/246 reads (18%) | catalogued as COSV58527576, COSV58534606; called by muse, mutect2, varscan2
- POTEF | c.927C>T p.L309= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs1428989621; called by muse, mutect2, varscan2
- PTGFRN | c.111T>C p.T37= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV101277225; called by muse, mutect2, varscan2
- QTRT1 | c.465C>T p.I155= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99138992; called by muse, mutect2
- REV3L | c.1770G>A p.L590= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV62625792; called by muse, mutect2
- RP1 | c.6402C>T p.F2134= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs755082655, COSV55110699; called by muse, mutect2, varscan2
- SIGLEC5 | c.1218C>T p.L406= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99706990; called by muse, mutect2, varscan2
- SSTR3 | c.136C>T p.L46= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV100142495; called by muse, mutect2, varscan2
- TBC1D8B | c.471G>A p.E157= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as COSV99343781; called by muse, mutect2, varscan2
- TEAD3 | c.1182C>T p.F394= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100132248; called by muse, mutect2, varscan2
- TREM1 | c.240C>T p.V80= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV99776041; called by muse, mutect2, varscan2
- TTN | c.87360G>A p.K29120= (on ENST00000591111; = p.K21696= on NM_003319.4) | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV100617674, COSV60470117; called by muse, mutect2
- TXK | c.894C>T p.I298= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV99972088; called by muse, mutect2, varscan2
- UIMC1 | c.1704C>T p.S568= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV101021998; called by muse, mutect2, varscan2
- WDR88 | c.186C>T p.A62= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV99403675; called by muse, mutect2
- ZDHHC6 | c.525C>T p.S175= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV101024308; called by muse, mutect2, varscan2
- ZNF331 | c.381G>A p.K127= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs1411784435, COSV53476952; called by muse, mutect2
- ZSWIM3 | c.933C>T p.T311= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99666022; called by muse, mutect2
- AQR | c.472-1035A>C | Intron (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- MIR522 | n.25G>A | RNA (SNP) | VAF 21/218 reads (10%) | catalogued as rs1012578303; called by muse, mutect2
- SERPINA13P | n.628G>A | RNA (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12769G>A | Intron (SNP) | VAF 6/94 reads (6%) | catalogued as COSV67451912; called by muse, mutect2
- TTLL8 | c.938+386C>T | Intron (SNP) | VAF 22/148 reads (15%) | catalogued as COSV99837907; called by muse, mutect2, varscan2
- XIST | n.7440G>A | RNA (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
